Surgical pathology report (de-identified scan), TCGA case TCGA-93-A4JO, project TCGA-LUAD (Lung Adenocarcinoma), tissue source site Washington University - St. Louis, specimen TCGA-93-A4JO-01A (Primary Tumor).

[page 1 of 4]
Surgical Pathology Report

Final

ICD-O-3
Adenocarcinoma, with mixed
Subtypes 8255/3
Site: Lung, lower lobe C34.3

SURGICAL PATHOLOGY REPORT FINAL

lw
10/2/12

Patient Name:

Address:

Gender:

DOB:

Service:

Cardiothoracic Surgery

Location:

MRN:

Hospital #:

Patient Type:

Accession #:

Taken:

Received:

Accessioned:

Reported:

Physician(s):

DIAGNOSIS:

- A. LYMPH NODE, LEVEL VII, EXCISION
- EIGHTEEN LYMPH NODES WITH NO EVIDENCE OF MALIGNANCY (18)
- B. LYMPH NODE, LEVEL X, EXCISION
- ONE LYMPH NODE WITH NO EVIDENCE OF MALIGNANCY (1)
- C. LYMPH NODE, LEVEL XI, EXCISION
- ONE LYMPH NODE WITH NO EVIDENCE OF MALIGNANCY (1)
- D. LYMPH NODE, LEVEL XII, EXCISION
- ONE LYMPH NODE WITH NO EVIDENCE OF MALIGNANCY (1)
- E. LUNG, RIGHT LOWER LOBE, LOBECTOMY
- ADENOCARCINOMA, MIXED TYPE (SOLID - 90%, ACINAR - 10%), POORLY-DIFFERENTIATED (1.5 CM), WITHOUT EVIDENCE OF VISCERAL PLEURA OR LYMPHOVASCULAR SPACE INVASION, RESECTION MARGINS NOT INVOLVED (SEE SYNOPSIS REPORT)
- PULMONARY CHONDROID HAMARTOMA (1.3 CM)
- FOUR LYMPH NODES WITH NO EVIDENCE OF MALIGNANCY (4)
- SUBPLEURAL PULMONARY FIBROSIS WITH BRONCHIAL METAPLASIA, METAPLASTIC BONE FORMATION, AND MUCOUS RETENTION CYST FORMATION
- F. LYMPH NODES, LEVEL IV R, EXCISION
- TWO LYMPH NODES WITH NO EVIDENCE OF MALIGNANCY (2)

By this signature, I attest that the above diagnosis is based upon my personal examination of the slides (and/or other material submitted in the diagnosis).

***Report Electronically Reviewed and Signed Off By

Intraoperative Consultation:

"Brought to frozen is a, 'right lower lobe lung,' consisting of a 191 gram, 12.8 x 7.7 x 3.3 cm lung lobe. Bronchial

[page 2 of 4]
SURGICAL PATHOLOGY REPORT

margin frozen as FS1. Sectioned to show two distinct masses, one measuring 1.9 x 1.6 x 1.5 cm and is closer to the base of the lung. The other measures 1.2 x 1.2 x 1.0 cm. Tissue from the larger mass is taken for research. Rest for permanents."

FS: Bronchial margin, biopsy
- "No evidence of malignancy,"

Microscopic Description and Comment:

Microscopic examination substantiates the above cited diagnosis.

History:

The patient is [REDACTED] with two lung nodules. Operative procedure: Right lower lobectomy.

Specimen(s) Received:

A: LYMPH NODE, LEVEL VII
B: LYMPH NODE, LEVEL X
C: LYMPH NODE, LEVEL XI
D: LYMPH NODE, LEVEL XII
E: LUNG, RIGHT LOWER LOBE
F: LYMPH NODE, LEVEL IVR

Gross Description:

The specimens are received in five formalin-filled containers, each labeled [REDACTED]. The first container is labeled "level VII lymph node." It contains two fragments of yellow fibroadipose tissue measuring 2.8 x 1.8 x 1.0 cm and 3.5 x 2.7 x 1.1 cm. multiple putative lymph nodes are identified within the yellow fibroadipose tissue. Labeled A1 to A4 - multiple putative lymph nodes. Jar 0.

The second container is labeled "level X lymph node." It contains a single putative lymph node measuring 0.9 x 0.9 x 0.8 cm. Labeled B1. Jar 0.

The third container is labeled "level XI lymph node." It contains two fragments of tan-gray tissue measuring 1.1 x 1.0 x 0.3 cm and 0.9 x 0.7 x 0.3 cm. Labeled C1. Jar 0.

The fourth container is labeled "lymph node level XII." It contains a single putative lymph node measuring 0.8 x 0.7 x 0.3 cm. Labeled D1. Jar 0.

The fifth container is labeled "right lower lobe lung." It contains a 10.5 x 10.0 x 9.7 cm lobe of lung. It has been previously sectioned to show a 1.5 x 1.1 x 1.4 cm firm white lesion. There is also a separate, 1.3 x 1.2 x 1.0 cm firm lesion superior to the larger mass. There is no pleural puckering over either mass. The bronchial margin appears normal. Multiple vascular structures are identified at the resection margin. They are grossly unremarkable. A few putative peribronchial lymph nodes are identified. Sections of the uninvolved lung show spongy tan lung parenchyma with no other focal lesions. Additionally in the container, a green cassette labeled "FS1," that holds multiple fragments of bronchial tissue measuring 1.5 x 1.2 x 0.2 cm in aggregate. Labeled E1 to E3 - larger mass; E4 and E5 - smaller more superior mass; E6 - uninvolved lung; E7 - vascular margin; E8 - bronchus; E9 - FS1; E10 and E11 - putative lymph nodes.

The sixth container is labeled "level IVR." It contains a 3.7 x 2.2 x 1.7 cm piece of yellow fibroadipose tissue. Two putative lymph nodes are dissected from the fibroadipose tissue, measuring up to 0.7 cm in greatest dimension. Labeled F1 and F2. Jar 1.

[page 3 of 4]
SURGICAL PATHOLOGY REPORT

SYNOPTIC REPORTING FORM FOR LUNG CARCINOMA

NEOPLASM

A neoplasm is present

HISTOPATHOLOGIC TYPE

The histologic classification of the tumor is carcinoma, mixed type Solid-90%, acinar-10%

HISTOLOGIC GRADE (G)

The grade of the tumor is poorly differentiated (G3)

TUMOR SIZE

The maximum dimension of the tumor is 1.5 cm

LYMPHATIC INVASION

Lymphatic invasion by tumor is absent (L0)

VENOUS INVASION

Venous invasion by tumor is absent (V0)

ARTERIAL INVASION

Arterial invasion by tumor is absent

PLEURAL INVOLVEMENT

Pleural involvement is absent

SAMPLED SPECIMEN MARGINS

The sampled surgical margins are uninvolved by tumor

NON-NEOPLASTIC TISSUE

Subpleural pulmonary fibrosis with bronchial metaplasia, metaplastic bone formation, and mucous retention cyst formation

PRIMARY TUMOR (T)

Tumor $\leq$ 2 cm in greatest dimension (T1a)

REGIONAL LYMPH NODES (N)

No regional lymph node metastasis histologically, no examination for ITC (pN0)

The total number of lymph nodes examined is 27

The total number of metastatically-involved lymph nodes is 0

DISTANT METASTASIS (M)

Distant metastasis cannot be assessed (MX)

STAGE GROUPING

The overall international stage is T1a/N0/M0 (Stage IA)

The pathologic stage assigned here should be regarded as provisional, and may change after integration of clinical data not provided with this specimen.

[page 4 of 4]
SURGICAL PATHOLOGY REPORT

Surgical Pathology report is available on-line on

Source: NCI Genomic Data Commons file 2fc05d61-f1f0-48cc-836c-c847d950c78b (TCGA-93-A4JO.54D7BAFD-D766-4EE6-A769-F57A858B5F44.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).